Gene-level copy-number profile of tumor specimen TCGA-FG-8185-01A from TCGA case TCGA-FG-8185, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 37.3 years (13,621 days).
Specimen TCGA-FG-8185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.8589a535-5f81-4ced-8060-e1f497c04c04.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-8185-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/435b70df-29af-4e55-8ce2-8e2e86af8abc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,929; copy number 2: 53,748; copy number 3: 1,431; copy number 4: 524; copy number 5: 95; copy number 6: 84.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FG-8185-01A-11D-2252-01): tumor purity 0.76, ploidy 4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:80,034,346–80,247,514, 9 genes: AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 179 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:1,957,589–4,243,912, 40 genes, copy number 5–6 (within-gene range 4–6): AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702.
- chr10:8,400,860–10,795,047, 23 genes, copy number 5: AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P.
- chr10:15,093,263–22,714,578, 116 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,508. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
